Somatic mutation profile of tumor specimen TCGA-EJ-7327-01A (aliquot TCGA-EJ-7327-01A-11D-2114-08) from TCGA case TCGA-EJ-7327, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.5 years (22,475 days).
Specimen TCGA-EJ-7327-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a25b611-776b-4e71-abd2-93701a6c79ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7327-10A (Blood Derived Normal), aliquot TCGA-EJ-7327-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd857ba1-0457-4b5c-a897-3eb532f925ed

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Frame Shift Del 4, Silent 4, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62717020; called by muse, mutect2, varscan2
- CCDC185 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs771980438, COSV64820567; called by muse, mutect2
- CDC5L | c.729A>T p.R243S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV65175690; called by muse, mutect2, varscan2
- CDX1 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51567753, COSV51569259; called by muse, mutect2, varscan2
- CORIN | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs571200712, COSV56689128; called by muse, mutect2, varscan2
- H2AC13 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs755363997, COSV62440647; called by muse, mutect2, varscan2
- IRF4 | c.548del p.P183Rfs*14 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as COSV101110816; called by mutect2, pindel, varscan2
- MTUS2 | c.1505T>A p.V502D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs199993580; called by muse, mutect2, varscan2
- NPY1R | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56713940; called by muse, mutect2, varscan2
- PHACTR1 | c.795del p.S266Vfs*47 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | catalogued as COSV60675252; called by mutect2, pindel, varscan2
- POU3F4 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs779536644, COSV64538294; called by mutect2, varscan2
- RCHY1 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61008153; called by muse, mutect2, varscan2
- SLFN13 | c.1819A>G p.I607V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV99540088; called by muse, varscan2
- TTC6 | c.370G>A p.A124T (on ENST00000267368; = p.A1490T on NM_001310135.3) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs777470939, COSV57447512; called by muse, mutect2, varscan2
- TUBA3C | c.1103T>A p.L368Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV68027918; called by muse, mutect2, varscan2
- WWC3 | c.378-1G>A p.X126_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV66502256; called by muse, mutect2, varscan2
- POGZ | c.3996_4009del p.D1333Lfs*7 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- PTEN | c.659del p.L220Qfs*3 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- YWHAQ | c.416_417dup p.Q140Nfs*4 | Frame Shift Ins (INS) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- AIM2 | c.726T>A p.I242= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV63699080; called by muse, mutect2, varscan2
- DNAJB5 | c.963C>T p.L321= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV56624992; called by muse, mutect2, varscan2
- GP5 | c.123G>A p.A41= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1043497790, COSV55462910; called by muse, mutect2, varscan2
- SCN4A | c.3465C>T p.G1155= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs566581547, COSV71126194; ClinVar: likely benign; called by muse, mutect2, varscan2
